Somatic mutation profile of tumor specimen MP2PRT-PAUKVY-TMP1-A (aliquot MP2PRT-PAUKVY-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAUKVY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,013 days).
Specimen MP2PRT-PAUKVY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69dfc200-0e23-432c-97bc-dde9698a9b26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKVY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKVY-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4abbafdd-29ea-4809-b23b-b5891c2ab154

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Frame Shift Ins 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BATF2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 104/717 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs376983784; called by muse, mutect2, varscan2
- NCKAP5 | c.2939C>T p.P980L | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1239165670, COSV58454360; called by mutect2, varscan2
- RNF17 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 262/649 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs753733648; called by muse, mutect2
- SH3BP4 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 190/632 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs139219220; called by muse, mutect2, varscan2
- TMEM178B | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 56/413 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.462); catalogued as rs1049056387; called by muse, mutect2, varscan2
- ADAMTS7 | c.2317dup p.R773Kfs*90 | Frame Shift Ins (INS) | VAF 63/588 reads (11%) | called by mutect2, pindel, varscan2
- B3GNT6 | c.84_85insCC p.W29Pfs*96 | Frame Shift Ins (INS) | VAF 58/688 reads (8%) | called by mutect2, pindel*
- BCL11A | c.2157C>A p.N719K (on ENST00000335712 / NM_001365609.1; = p.N753K on NM_022893.4) | Missense Mutation (SNP) | VAF 82/673 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- COL13A1 | c.1205C>A p.A402E (on ENST00000398978 / NM_001130103.2; = p.A345E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.706); called by muse, mutect2
- CPNE2 | c.1294_1296delinsTACT p.T432Yfs*18 | Frame Shift Ins (INS) | VAF 66/583 reads (11%) | called by pindel, varscan2*
- LYST | c.257T>C p.I86T | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MBTPS1 | c.2085G>C p.M695I | Missense Mutation (SNP) | VAF 141/349 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH5 | c.718T>G p.S240A | Missense Mutation (SNP) | VAF 222/542 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- VPS13B | c.4804A>G p.R1602G | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NCR3LG1 | c.351A>G p.A117= | Silent (SNP) | VAF 18/636 reads (3%) | called by muse, mutect2
